Somatic mutation profile of cancer-model specimen HCM-CSHL-0243-C18-85A (3D Organoid; aliquot HCM-CSHL-0243-C18-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0243-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,279 days).
Specimen HCM-CSHL-0243-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dbc9140-ccc4-4d9f-8a5a-20e67de1a82f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0243-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0243-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bbbfb9e-a991-496c-b309-f27a89e9d3c5

The open-access MAF lists 145 somatic variants for this specimen: 96 protein-altering or splice-affecting, 29 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 29, Intron 13, Nonsense Mutation 8, RNA 5, Frame Shift Ins 4, Frame Shift Del 3, Splice Region 2, In Frame Ins 1, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 77/78 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886041700, CM062439, CM970153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 74/128 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 165/349 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 137/224 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140497119; called by muse, mutect2, varscan2
- AGPAT4 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 268/559 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs781252538, COSV57248906; called by muse, mutect2, varscan2
- ATRX | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 78/79 reads (99%) | catalogued as COSV64878009; called by muse, mutect2, varscan2
- BTNL8 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 253/525 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs373083701; called by muse, mutect2, varscan2
- CARD9 | c.1078-5G>A | Splice Region (SNP) | VAF 82/160 reads (51%) | catalogued as rs746317918; called by muse, mutect2, varscan2
- CDH18 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 191/396 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56922914; called by muse, mutect2, varscan2
- CFAP65 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs760496355, COSV58562117; called by muse, mutect2, varscan2
- CHDH | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 117/260 reads (45%) | catalogued as rs1377660740; called by muse, mutect2, varscan2
- CLSTN2 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs199508939, COSV71717984, COSV71725726; called by muse, mutect2, varscan2
- COL6A3 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 160/335 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776312405, COSV99796426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.8776G>A p.E2926K | Missense Mutation (SNP) | VAF 79/141 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56476438; called by muse, mutect2, varscan2
- DCLK1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 105/225 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as rs750026852, COSV55201416; called by muse, mutect2, varscan2
- DICER1 | c.5564G>A p.R1855Q | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100602180; called by muse, mutect2, varscan2
- DIDO1 | c.4801G>A p.V1601M | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1388945963; called by muse, mutect2, varscan2
- DNAJC10 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs201121755, COSV51137935; called by muse, mutect2, varscan2
- EPAS1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 256/532 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs375544083, COSV55390884; called by muse, mutect2, varscan2
- EPOP | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1370451170; called by muse, mutect2, varscan2
- EVL | c.673G>A p.A225T (on ENST00000402714 / NM_001330221.2; = p.A227T on NM_016337.3) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs201550659; called by muse, mutect2, varscan2
- FAT2 | c.12785G>A p.R4262H | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs750561477, COSV99942932; called by muse, mutect2, varscan2
- GDNF | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as rs769492137, COSV100427543, COSV58479206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFC3 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs150167969, COSV65552500; called by muse, mutect2, varscan2
- LCE2C | c.108C>A p.C36* | Nonsense Mutation (SNP) | VAF 116/543 reads (21%) | catalogued as COSV100909422; called by muse, mutect2, varscan2
- LPCAT2 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 119/216 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV50896204; called by muse, mutect2, varscan2
- MAP6 | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 123/258 reads (48%) | catalogued as COSV59075312; called by muse, mutect2, varscan2
- MRM3 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58679726; called by muse, varscan2
- MROH2A | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs541647931; called by muse, mutect2, varscan2
- MROH6 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 158/357 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs1455305772, COSV99435356; called by muse, mutect2, varscan2
- MUC12 | c.892C>T p.R298C (on ENST00000379442; = p.R155C on NM_001164462.1) | Missense Mutation (SNP) | VAF 240/491 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs571855490, COSV65198830; called by muse, mutect2, varscan2
- MYO16 | c.4934C>A p.A1645E | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs191971963; called by muse, mutect2, varscan2
- NLGN4Y | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52970681, COSV99946191; called by muse, mutect2, varscan2
- NUP133 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1164570532; called by muse, mutect2, varscan2
- PIF1 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 190/396 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs377317303; called by muse, mutect2, varscan2
- PLXNA4 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs774798274, COSV58110834; called by muse, mutect2, varscan2
- PNPLA2 | c.1176-5C>T | Splice Region (SNP) | VAF 249/518 reads (48%) | catalogued as rs1458057753; called by muse, mutect2, varscan2
- PNPLA7 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs145427614; called by muse, mutect2, varscan2
- PRDM15 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 95/217 reads (44%) | catalogued as rs568404668, COSV54156788; called by muse, mutect2, varscan2
- PXDNL | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100685952; called by muse, mutect2, varscan2
- ROPN1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV51739399; called by muse, mutect2, varscan2
- SETD2 | c.5122C>T p.R1708* | Nonsense Mutation (SNP) | VAF 103/218 reads (47%) | catalogued as rs774671060, COSV57449337; called by muse, mutect2, varscan2
- SFT2D1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768482376; called by muse, mutect2, varscan2
- SHANK3 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.736); catalogued as rs1287997418; called by muse, mutect2, varscan2
- SPRYD3 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs758900368, COSV56852699; called by muse, mutect2, varscan2
- SQLE | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747188670, COSV56283201; called by muse, mutect2, varscan2
- SYNE2 | c.12227_12229del p.E4076del | In Frame Del (DEL) | VAF 80/180 reads (44%) | catalogued as rs748493867; called by pindel, varscan2
- SYNE2 | c.14480G>A p.R4827H | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs774421754, COSV59945467; called by muse, mutect2, varscan2
- TET1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV65386962; called by muse, mutect2, varscan2
- TRIM54 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs748843079, COSV56085510; called by muse, mutect2, varscan2
- TRPC7 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 121/123 reads (98%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs372192731; called by muse, mutect2, varscan2
- TRPM1 | c.2224C>T p.R742W | Missense Mutation (SNP) | VAF 261/527 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs373109371; called by muse, mutect2, varscan2
- VMO1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV54495760; called by muse, mutect2, varscan2
- WFIKKN1 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 161/312 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs752283984; called by muse, mutect2, varscan2
- AAK1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD17 | c.5765C>T p.S1922F | Missense Mutation (SNP) | VAF 24/819 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- APC | c.4089_4093del p.S1364Cfs*9 | Frame Shift Del (DEL) | VAF 138/146 reads (95%) | called by mutect2, pindel, varscan2
- ARMH1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATRIP | c.669_670insCTC p.V223_S224insL | In Frame Ins (INS) | VAF 36/80 reads (45%) | called by mutect2, pindel, varscan2
- BCL9 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BIRC6 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- BIRC6 | c.8091T>G p.N2697K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, varscan2
- C1orf131 | c.11A>T p.D4V | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CDH12 | c.1520T>G p.I507S | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHM | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 140/141 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CILP2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP1 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 106/397 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CPLANE1 | c.8752_8753dup p.G2920Efs*17 | Frame Shift Ins (INS) | VAF 53/154 reads (34%) | called by mutect2, pindel, varscan2
- DDIAS | c.2130A>C p.E710D | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DHX38 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- DNAH11 | c.3187G>T p.E1063* | Nonsense Mutation (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- DNAH5 | c.4905A>C p.L1635F | Missense Mutation (SNP) | VAF 164/363 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELF3 | c.974_975insAT p.Y326Sfs*5 | Frame Shift Ins (INS) | VAF 49/94 reads (52%) | called by mutect2, pindel, varscan2
- EML6 | c.5637T>A p.N1879K | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- GBE1 | c.442del p.S148Vfs*24 | Frame Shift Del (DEL) | VAF 60/148 reads (41%) | called by mutect2, pindel, varscan2
- GIN1 | c.1562T>G p.L521* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- IGSF11 | c.1067C>T p.S356F (on ENST00000393775 / NM_001015887.3; = p.S355F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/331 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KRT27 | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LUZP2 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MED26 | c.1276A>C p.T426P | Missense Mutation (SNP) | VAF 126/266 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYNN | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1B | c.2099G>T p.R700M | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NELL2 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 91/377 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOTCH4 | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 268/269 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPLOC4 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDIA6 | c.905dup p.P303Afs*5 | Frame Shift Ins (INS) | VAF 53/156 reads (34%) | called by mutect2, pindel, varscan2
- PFKFB2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 86/481 reads (18%) | PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PITPNM2 | c.1014T>G p.D338E | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLAG1 | c.1072_1073del p.S358Lfs*23 | Frame Shift Del (DEL) | VAF 60/172 reads (35%) | called by pindel, varscan2
- PPP1R13B | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDK1 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETD2 | c.6584_6588dup p.V2197Tfs*53 | Frame Shift Ins (INS) | VAF 143/402 reads (36%) | called by mutect2, pindel, varscan2
- TALDO1 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 147/370 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TTN | c.93012T>A p.H31004Q (on ENST00000591111; = p.H23580Q on NM_003319.4) | Missense Mutation (SNP) | VAF 78/196 reads (40%) | PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZCRB1 | c.177G>C p.L59F | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ADGRL2 | c.1233T>G p.A411= | Silent (SNP) | VAF 101/157 reads (64%) | called by muse, mutect2, varscan2
- AMELY | c.534C>T p.P178= (on ENST00000383036 / NM_001364814.1; = p.P164= on NM_001143.1) | Silent (SNP) | VAF 99/99 reads (100%) | called by muse, mutect2, varscan2
- CLMN | c.2319G>A p.E773= | Silent (SNP) | VAF 58/130 reads (45%) | called by muse, mutect2, varscan2
- DNAH17 | c.849C>T p.N283= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as rs541514193, COSV67755032; called by muse, mutect2
- EMILIN1 | c.2406C>T p.D802= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1188315768; called by muse, mutect2
- EML2 | c.24A>G p.L8= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs1036347379; called by muse, varscan2
- FAM83G | c.306C>T p.S102= | Silent (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- FUT5 | c.600G>A p.S200= | Silent (SNP) | VAF 204/488 reads (42%) | catalogued as rs755502536, COSV53138682; called by muse, mutect2, varscan2
- H2AW | c.318T>C p.G106= | Silent (SNP) | VAF 54/1008 reads (5%) | catalogued as rs758423488, COSV64209520; called by muse, mutect2
- LAMC3 | c.1771C>T p.L591= | Silent (SNP) | VAF 71/186 reads (38%) | called by muse, mutect2, varscan2
- MBD2 | c.126C>T p.A42= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- MCOLN1 | c.585G>A p.V195= | Silent (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- MPPE1 | c.1170C>T p.L390= | Silent (SNP) | VAF 69/69 reads (100%) | catalogued as rs761546673; called by muse, mutect2, varscan2
- MUC16 | c.13119C>A p.P4373= | Silent (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- NUDT17 | c.300G>A p.Q100= | Silent (SNP) | VAF 90/464 reads (19%) | called by muse, mutect2, varscan2
- OPCML | c.327C>T p.D109= | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as rs144949245; called by muse, mutect2, varscan2
- PCDHB7 | c.1209G>C p.L403= | Silent (SNP) | VAF 72/159 reads (45%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.1332C>T p.D444= | Silent (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- PRKG1 | c.1281C>T p.I427= | Silent (SNP) | VAF 97/177 reads (55%) | catalogued as rs868492323; called by muse, mutect2, varscan2
- RRAD | c.888C>T p.R296= | Silent (SNP) | VAF 71/150 reads (47%) | called by muse, varscan2
- RYR3 | c.2673C>T p.F891= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs1018585519; called by muse, mutect2, varscan2
- SAMD8 | c.771A>G p.Q257= | Silent (SNP) | VAF 8/236 reads (3%) | called by muse, mutect2
- SLC45A4 | c.1620C>T p.G540= (on ENST00000517878 / NM_001286646.2; = p.G489= on NM_001080431.2) | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs376263480; called by muse, varscan2
- SUGCT | c.976T>C p.L326= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs923708159; called by muse, mutect2, varscan2
- TARM1 | c.162G>A p.T54= (on ENST00000616041 / NM_001330650.1; = p.T46= on NM_001135686.3) | Silent (SNP) | VAF 13/227 reads (6%) | catalogued as rs768953656; called by muse, mutect2
- TRPA1 | c.1374T>C p.R458= | Silent (SNP) | VAF 107/279 reads (38%) | catalogued as rs771776111; called by muse, mutect2, varscan2
- WWC1 | c.2022A>G p.Q674= | Silent (SNP) | VAF 88/175 reads (50%) | called by muse, mutect2, varscan2
- ZBTB2 | c.99A>G p.V33= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as COSV57311565, COSV57312377; called by muse, mutect2
- ZNF93 | c.969G>A p.K323= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs765870925; called by muse, mutect2, varscan2
- ABCG1 | c.1808+26G>A | Intron (SNP) | VAF 96/196 reads (49%) | catalogued as rs2276234; called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.1068C>T | RNA (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- C5orf17 | n.236C>G | RNA (SNP) | VAF 16/25 reads (64%) | catalogued as rs544513975; called by muse, mutect2, varscan2
- CILP2 | c.164-12C>T | Intron (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- DLG2 | c.205-21860G>A | Intron (SNP) | VAF 57/96 reads (59%) | catalogued as rs755938527; called by muse, mutect2, varscan2
- ENTPD6 | c.1243+22_1243+71del | Intron (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel
- LY9 | c.1072+29C>A | Intron (SNP) | VAF 41/163 reads (25%) | called by muse, varscan2
- LYRM4 | c.208-34723C>T | Intron (SNP) | VAF 138/303 reads (46%) | catalogued as rs1326669740; called by muse, mutect2, varscan2
- NORAD | n.490G>T | RNA (SNP) | VAF 138/280 reads (49%) | called by muse, mutect2, varscan2
- NPIPB14P | n.140C>G | RNA (SNP) | VAF 77/196 reads (39%) | catalogued as rs772162065; called by muse, mutect2, varscan2
- PDXK | c.88-1615G>A | Intron (SNP) | VAF 185/405 reads (46%) | catalogued as rs752593956; called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1510C>T | Intron (SNP) | VAF 115/211 reads (55%) | catalogued as rs1365312688; called by muse, varscan2
- RNF40 | c.*924G>A | 3'UTR (SNP) | VAF 102/208 reads (49%) | called by muse, mutect2, varscan2
- RORA | c.196+51377G>C | Intron (SNP) | VAF 88/192 reads (46%) | catalogued as COSV55037446, COSV55042395; called by muse, mutect2, varscan2
- RPN2 | c.-21C>T | 5'UTR (SNP) | VAF 83/169 reads (49%) | catalogued as rs1328084199; called by muse, mutect2, varscan2
- SNURFL | n.279G>A | RNA (SNP) | VAF 80/80 reads (100%) | catalogued as rs759760357; called by muse, mutect2, varscan2
- TSC22D4 | c.979-34C>A | Intron (SNP) | VAF 122/225 reads (54%) | called by muse, mutect2, varscan2
- TTC19 | c.995-18C>A | Intron (SNP) | VAF 66/155 reads (43%) | called by muse, mutect2, varscan2
- Z96074.1 | n.151+3135C>A | Intron (SNP) | VAF 48/48 reads (100%) | called by muse, mutect2, varscan2
- ZNF496 | c.651+453C>T | Intron (SNP) | VAF 59/242 reads (24%) | catalogued as rs1309991710, COSV54174282; called by muse, mutect2, varscan2
